Gene-level copy-number profile of tumor specimen TCGA-02-0266-01A from TCGA case TCGA-02-0266, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,303 days).
Specimen TCGA-02-0266-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.fac9f381-5468-4b70-bc55-5e193ac1dc3e.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,019 have no estimate.
https://portal.gdc.cancer.gov/files/83694da8-1925-4402-9f14-2feb6817ebcb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 508; copy number 2: 38,048; copy number 3: 5,958; copy number 4: 9,168; copy number 5: 1,075; copy number 6: 847.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0266-01): tumor purity 0.84, ploidy 2.49, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,922 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:68,328,308–70,414,624, 35 genes, copy number 5: PGM5, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P, MAMDC2-AS1, MAMDC2, RNU2-5P, SMC5-AS1, RPL24P8, SMC5, AL162390.1, Y_RNA, KLF9.
- chr9:70,579,163–70,730,856, 3 genes, copy number 5: RN7SL726P, AL159990.2, AL159990.1.
- chr9:80,357,029–81,410,630, 6 genes, copy number 5: NPAP1P4, MTCO1P51, MTND2P9, RPS19P6, AL138749.1, RPS20P25.
- chr9:82,405,188–82,744,792, 7 genes, copy number 5: AL162726.1, MTCO3P40, AL162726.2, AL162726.4, AL356490.1, AL353774.1, RPS6P12.
- chr9:83,739,425–84,657,077, 16 genes, copy number 5 (within-gene range 3–5): GKAP1, AL354733.1, AL354733.2, KIF27, C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2, SLC28A3, AL356134.1, AL157886.1, AL354692.1.
- chr9:85,159,682–89,498,130, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:89,797,880–90,642,862, 13 genes, copy number 5 (within-gene range 3–5): BX470209.2, BX470209.1, AL161629.1, MIR4290HG, MIR4290, IL6RP1, AL161629.2, AL353649.1, OR7E31P, OR7E116P, LINC01508, LINC01501, DIRAS2.
- chr9:90,801,787–91,361,918, 11 genes, copy number 5 (within-gene range 3–5): SYK, AL162585.1, AL355607.1, AL355607.2, AL158071.3, AL158071.2, LINC00484, LINC00484, AL158071.1, AL158071.4, AUH.
- chr9:91,563,091–91,950,228, 4 genes, copy number 5 (within-gene range 3–5): ROR2, PAICSP2, MIR3910-1, MIR3910-2.
- chr9:93,417,855–96,121,154, 66 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr9:96,687,050–98,796,965, 57 genes, copy number 5 (within-gene range 3–5): AL589843.1, AL589843.2, ZNF510, ZNF782, MFSD14C, PTMAP11, AL158827.1, NUTM2G, YRDCP2, CTSV, TCEA1P1, GAS2L1P2, VN1R51P, FAM220CP, AL445670.1, ANKRD18CP, RNU6-798P, AL590705.3, ZNF322P1, AL590705.1, AL590705.2, SUGT1P4-STRA6LP, STRA6LP, SUGT1P4, AL512590.2, CCDC180, MIR1302-8, AL512590.1, AL512590.3, TDRD7, TMOD1, AL162385.1, TSTD2, NCBP1, AL162385.2, XPA, KRT18P13, PTCSC2, AL445531.1, FOXE1, TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6.
- chr9:99,145,840–99,974,534, 17 genes, copy number 5 (within-gene range 4–5): RNA5SP290, AL162427.1, RN7SL794P, ALG2, SEC61B, RN7SKP225, KRT8P11, NAMA, AL137067.2, AL137067.3, AL137067.1, AL359710.1, STX17-AS1, AL162394.1, NR4A3, STX17, AL358937.1.
- chr9:102,256,604–102,657,514, 5 genes, copy number 5: RNU6-329P, AL442644.2, AL442644.1, LINC00587, ZYG11AP1.
- chr9:104,504,263–104,928,892, 17 genes, copy number 5: OR13F1, AL450426.1, OR13C4, OR13C3, OR13C8, OR13D2P, OR13C5, OR13C2, OR13C9, OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1.
- chr9:105,993,310–106,740,875, 1 gene, copy number 5 (within-gene range 4–5): LINC01505.
- chr9:106,584,142–138,124,624, 748 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:752,579–9,760,901, 337 genes, copy number 6 (broad region; genes not listed).
- chr12:15,322,257–32,993,754, 305 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:55,636,860–56,787,790, 88 genes, copy number 6 (broad region; genes not listed).
- chr12:57,028,517–59,789,855, 84 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr12:70,515,870–70,920,738, 4 genes, copy number 6 (within-gene range 3–6): PTPRB, AC083809.1, PTPRR, FAHD2P1.
- chr12:73,648,666–73,649,039, 1 gene, copy number 6: AC087879.1.
- chr12:75,275,979–75,511,636, 8 genes, copy number 6 (within-gene range 1–6): CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1.
- chr12:75,600,047–75,698,816, 5 genes, copy number 6: AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1.

Autosomal genes at a single copy (total copy number 1): 508. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
